FM case AD1635 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/6b408736-2a10-4b75-9524-09cb7a2c9c14

Female, 54.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
